Somatic mutation profile of cancer-model specimen HCM-STAN-0841-C18-85A (3D Organoid, passage 8; aliquot HCM-STAN-0841-C18-85A-01D-A882-36), derived from the primary tumor of HCMI case HCM-STAN-0841-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVB; Tumor grade: G1; Age at diagnosis: 62.2 years (22,736 days).
Specimen HCM-STAN-0841-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d52c8c8d-6993-476e-a897-caa0cf8ec900.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-STAN-0841-C18-11A (Solid Tissue Normal), aliquot HCM-STAN-0841-C18-11A-11D-A882-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6f36390b-fdff-4229-8b26-b3e9fdeccd53

The open-access MAF lists 153 somatic variants for this specimen: 104 protein-altering or splice-affecting, 43 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 86, Silent 43, Nonsense Mutation 7, Frame Shift Del 3, Frame Shift Ins 3, Splice Region 3, Intron 3, 5'UTR 1, 3'UTR 1, RNA 1, Splice Site 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC39 | c.286C>T p.R96* | Nonsense Mutation (SNP) | VAF 166/259 reads (64%) | catalogued as rs778577109; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 142/306 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- ACIN1 | c.4018C>T p.R1340C | Missense Mutation (SNP) | VAF 201/201 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.818); catalogued as COSV52972567; called by muse, mutect2, varscan2
- AIM2 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 152/313 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs149819770; called by muse, mutect2, varscan2
- ALK | c.2629G>T p.A877S | Missense Mutation (SNP) | VAF 149/290 reads (51%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs746442213, COSV66594998; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AMOTL2 | c.1964G>A p.G655D | Missense Mutation (SNP) | VAF 235/366 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.602); catalogued as rs1405117987; called by muse, mutect2, varscan2
- ARFGEF3 | c.5146G>A p.V1716M | Missense Mutation (SNP) | VAF 107/280 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52450815; called by muse, mutect2, varscan2
- ARHGEF40 | c.3778C>T p.R1260C | Missense Mutation (SNP) | VAF 206/206 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs573599814, COSV53879661; called by muse, mutect2, varscan2
- ASTN2 | c.143_164del p.L48Pfs*11 | Frame Shift Del (DEL) | VAF 116/514 reads (23%) | catalogued as rs1242458310; called by mutect2, varscan2
- ATG2A | c.2035C>T p.R679W | Missense Mutation (SNP) | VAF 265/485 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as rs533644989, COSV65967112, COSV65967352; called by muse, mutect2, varscan2
- BCR | c.1461G>A p.A487= | Splice Region (SNP) | VAF 69/230 reads (30%) | catalogued as rs201526307, COSV100006358; called by muse, mutect2, varscan2
- CCDC185 | c.1529C>T p.A510V | Missense Mutation (SNP) | VAF 233/483 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.117); catalogued as rs867870627; called by muse, mutect2, varscan2
- CCDC92 | c.881G>A p.R294Q | Missense Mutation (SNP) | VAF 387/791 reads (49%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.768); catalogued as rs371993242; called by muse, mutect2, varscan2
- CERS3 | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 266/266 reads (100%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as rs563532463, COSV52569480; called by muse, mutect2, varscan2
- CROCC | c.3038G>A p.R1013Q | Missense Mutation (SNP) | VAF 167/180 reads (93%) | SIFT tolerated (0.13); PolyPhen benign (0.073); catalogued as rs750711172, COSV100978271; called by muse, mutect2, varscan2
- CRY2 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 165/699 reads (24%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs752759191, COSV69888210; called by muse, mutect2, varscan2
- CUL2 | c.208C>T p.R70W | Missense Mutation (SNP) | VAF 85/204 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.606); catalogued as rs754713861, COSV66078712; called by muse, mutect2, varscan2
- CXXC5 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 321/591 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs113958458; called by muse, mutect2, varscan2
- DCLK1 | c.2101C>T p.R701C (on ENST00000360631 / NM_001330072.2; = p.D725= on NM_004734.5) | Missense Mutation (SNP) | VAF 113/580 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); catalogued as COSV55189268; called by muse, mutect2, varscan2
- ELOVL2 | c.640G>A p.V214M | Missense Mutation (SNP) | VAF 132/302 reads (44%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.656); catalogued as rs202019761, COSV61156962; called by muse, mutect2, varscan2
- FBLN2 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 120/404 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.466); catalogued as rs760367076; called by muse, mutect2, varscan2
- GK | c.1462G>A p.V488I (on ENST00000427190 / NM_001205019.2; = p.V482I on NM_000167.6) | Missense Mutation (SNP) | VAF 105/485 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs768478671, COSV66732332; called by muse, mutect2, varscan2
- GOLGA1 | c.2266C>T p.R756W | Missense Mutation (SNP) | VAF 67/202 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747290499; called by muse, mutect2, varscan2
- HOXC10 | c.482C>T p.T161M | Missense Mutation (SNP) | VAF 341/679 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.212); catalogued as rs1343516622, COSV57726540; called by muse, mutect2, varscan2
- HYDIN | c.1449G>A p.A483= | Splice Region (SNP) | VAF 82/169 reads (49%) | catalogued as rs1224728357, COSV55490046; called by muse, mutect2, varscan2
- IRX2 | c.1135G>A p.G379S | Missense Mutation (SNP) | VAF 267/582 reads (46%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.998); catalogued as COSV100121757; called by muse, mutect2, varscan2
- LIMS2 | c.50G>A p.R17H (on ENST00000355119 / NM_001161403.3; = p.R41H on NM_017980.4) | Missense Mutation (SNP) | VAF 235/489 reads (48%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as rs775450533; called by muse, mutect2, varscan2
- LRRC4B | c.1682C>T p.T561M | Missense Mutation (SNP) | VAF 218/350 reads (62%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.673); catalogued as COSV65349702; called by muse, mutect2, varscan2
- LRRTM3 | c.1636G>T p.E546* | Nonsense Mutation (SNP) | VAF 194/493 reads (39%) | catalogued as COSV63661986; called by muse, mutect2
- MAP3K19 | c.1058del p.G353Vfs*24 | Frame Shift Del (DEL) | VAF 134/311 reads (43%) | catalogued as COSV59638811, COSV59640258; called by mutect2, pindel, varscan2
- MARK1 | c.1832G>A p.R611Q | Missense Mutation (SNP) | VAF 140/558 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs776989724, COSV65070850; called by muse, mutect2, varscan2
- MGAM2 | c.970C>T p.R324W | Missense Mutation (SNP) | VAF 50/349 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs548068484; called by muse, mutect2
- MORC1 | c.2641dup p.I881Nfs*11 | Frame Shift Ins (INS) | VAF 58/100 reads (58%) | catalogued as rs757379917; called by mutect2, varscan2
- MRGPRE | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 146/548 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.391); catalogued as rs754926111, COSV67745840; called by muse, mutect2, varscan2
- MSN | c.1135C>T p.R379W | Missense Mutation (SNP) | VAF 239/507 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.117); catalogued as rs766622413, COSV64303252; called by muse, mutect2, varscan2
- MYO1E | c.1669C>T p.R557C | Missense Mutation (SNP) | VAF 171/171 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1178412708, COSV99896840; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NEK5 | c.2075G>A p.R692H | Missense Mutation (SNP) | VAF 90/561 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs200564973; called by muse, mutect2, varscan2
- NT5DC3 | c.466C>T p.R156W | Missense Mutation (SNP) | VAF 29/175 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs145829801; called by muse, mutect2, varscan2
- OR10G9 | c.457C>A p.L153M | Missense Mutation (SNP) | VAF 47/405 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.949); catalogued as COSV100901531, COSV66686216; called by muse, varscan2
- OR4C6 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 165/382 reads (43%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.006); catalogued as rs772626217, COSV58604155; called by muse, mutect2, varscan2
- PAPPA2 | c.1912G>A p.D638N | Missense Mutation (SNP) | VAF 192/390 reads (49%) | SIFT tolerated (0.34); PolyPhen benign (0.044); catalogued as rs1168232006, COSV62772967; called by muse, varscan2
- PBX4 | c.1033G>T p.A345S | Missense Mutation (SNP) | VAF 26/280 reads (9%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as rs771225104, COSV99232070; called by muse, mutect2
- PCDHA8 | c.1855C>T p.R619C | Missense Mutation (SNP) | VAF 254/527 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as rs145175505, COSV65323207, COSV65332790; called by muse, mutect2, varscan2
- PLXNA3 | c.691G>A p.V231I | Missense Mutation (SNP) | VAF 288/700 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as rs782778301; called by muse, mutect2, varscan2
- POMC | c.755C>T p.T252M | Missense Mutation (SNP) | VAF 102/499 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs775998713, COSV53034904; called by muse, mutect2, varscan2
- RBMS3 | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 168/258 reads (65%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.701); catalogued as rs745458478, COSV56138386; called by muse, mutect2, varscan2
- RIN3 | c.2939G>A p.R980Q | Missense Mutation (SNP) | VAF 181/182 reads (99%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.543); catalogued as rs1207521353, COSV104370381; called by muse, varscan2
- S1PR1 | c.1132G>A p.V378I | Missense Mutation (SNP) | VAF 129/262 reads (49%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs769569528, COSV59514504; called by muse, mutect2, varscan2
- SHROOM2 | c.3131G>A p.R1044Q | Missense Mutation (SNP) | VAF 374/701 reads (53%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs776355945; called by muse, mutect2, varscan2
- SLC13A3 | c.1603G>A p.A535T | Missense Mutation (SNP) | VAF 113/509 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as rs139768929; called by muse, mutect2, varscan2
- SLC66A1L | n.446T>G | Splice Region (SNP) | VAF 55/162 reads (34%) | catalogued as COSV70246910; called by muse, mutect2, varscan2
- TKTL2 | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 230/232 reads (99%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs905050983; called by muse, mutect2, varscan2
- TMEM185B | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 226/417 reads (54%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs1470518543; called by muse, varscan2
- TTC6 | c.3274C>T p.R1092* | Nonsense Mutation (SNP) | VAF 125/125 reads (100%) | catalogued as rs781407244; called by muse, mutect2, varscan2
- XRCC3 | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 253/253 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs780262052; called by muse, mutect2, varscan2
- ZNF324B | c.968G>A p.R323Q | Missense Mutation (SNP) | VAF 100/395 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.968); catalogued as rs919613361, COSV100351671; called by muse, mutect2, varscan2
- ABCB5 | c.2011-1G>T p.X671_splice (on ENST00000404938 / NM_001163941.2; = p.X226_splice on NM_178559.6) | Splice Site (SNP) | VAF 105/283 reads (37%) | called by muse, mutect2, varscan2
- AC068580.4 | c.1471G>A p.V491I | Missense Mutation (SNP) | VAF 188/455 reads (41%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- ACAT2 | c.820C>T p.L274F | Missense Mutation (SNP) | VAF 189/349 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- AFF2 | c.3182C>A p.P1061H | Missense Mutation (SNP) | VAF 132/305 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- APC | c.2820_2841delinsTTC p.E941Sfs*8 | Frame Shift Del (DEL) | VAF 97/249 reads (39%) | called by pindel, varscan2*
- APC | c.4166_4170delinsAGA p.S1389* | Nonsense Mutation (DEL) | VAF 170/413 reads (41%) | called by pindel, varscan2*
- CAPRIN2 | c.930C>G p.N310K | Missense Mutation (SNP) | VAF 63/259 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- CCDC18 | c.1024A>C p.K342Q | Missense Mutation (SNP) | VAF 56/315 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- CEP83 | c.1499A>T p.K500M | Missense Mutation (SNP) | VAF 84/399 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- CLDN18 | c.464A>G p.Y155C | Missense Mutation (SNP) | VAF 82/231 reads (35%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.716); called by muse, mutect2, varscan2
- DBF4 | c.1678G>A p.E560K | Missense Mutation (SNP) | VAF 75/489 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DGKI | c.3083G>T p.G1028V | Missense Mutation (SNP) | VAF 119/357 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- DMD | c.2844G>A p.M948I | Missense Mutation (SNP) | VAF 227/399 reads (57%) | SIFT tolerated (0.42); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DMRTA1 | c.*3_*8dup | In Frame Ins (INS) | VAF 29/76 reads (38%) | called by mutect2, varscan2
- DPEP2 | c.293A>T p.Q98L | Missense Mutation (SNP) | VAF 52/349 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DPEP2NB | c.237G>T p.K79N | Missense Mutation (SNP) | VAF 113/713 reads (16%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- EEF1A1 | c.443T>C p.L148P | Missense Mutation (SNP) | VAF 72/305 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FNBP4 | c.1033G>C p.V345L | Missense Mutation (SNP) | VAF 55/374 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- GABPA | c.116G>A p.S39N | Missense Mutation (SNP) | VAF 66/307 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GSE1 | c.1675G>A p.D559N | Missense Mutation (SNP) | VAF 108/639 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- HEATR5B | c.4798T>C p.C1600R | Missense Mutation (SNP) | VAF 39/217 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HIVEP1 | c.455A>C p.D152A | Missense Mutation (SNP) | VAF 178/409 reads (44%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- ITIH5 | c.926C>A p.T309N | Missense Mutation (SNP) | VAF 52/250 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- KIF13B | c.3125G>T p.G1042V | Missense Mutation (SNP) | VAF 86/187 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- KLHL3 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 186/392 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KXD1 | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 80/278 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- LAMB3 | c.559G>T p.G187W | Missense Mutation (SNP) | VAF 61/309 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LEMD3 | c.2632G>A p.A878T | Missense Mutation (SNP) | VAF 164/401 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- LRP1B | c.3847C>A p.L1283I | Missense Mutation (SNP) | VAF 76/326 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by mutect2, varscan2
- LRTM2 | c.869G>A p.S290N | Missense Mutation (SNP) | VAF 150/604 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, varscan2
- MPHOSPH8 | c.406T>A p.S136T | Missense Mutation (SNP) | VAF 77/433 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NRP1 | c.1204C>T p.R402* | Nonsense Mutation (SNP) | VAF 81/339 reads (24%) | called by muse, mutect2, varscan2
- NUTM1 | c.1223C>T p.P408L | Missense Mutation (SNP) | VAF 218/218 reads (100%) | SIFT tolerated (0.12); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- PCDHAC1 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 240/513 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDHB11 | c.507C>A p.S169R | Missense Mutation (SNP) | VAF 152/309 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- PCDHGA8 | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 206/423 reads (49%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLPPR4 | c.917T>G p.V306G | Missense Mutation (SNP) | VAF 170/314 reads (54%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- PTGS2 | c.1526T>C p.V509A | Missense Mutation (SNP) | VAF 15/470 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); called by muse, mutect2
- RP1 | c.4465G>A p.A1489T | Missense Mutation (SNP) | VAF 104/216 reads (48%) | SIFT tolerated (0.34); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RPRD2 | c.1831A>G p.I611V | Missense Mutation (SNP) | VAF 185/433 reads (43%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SHANK2 | c.4689T>G p.Y1563* | Nonsense Mutation (SNP) | VAF 193/446 reads (43%) | called by muse, mutect2, varscan2
- SLITRK5 | c.412A>T p.N138Y | Missense Mutation (SNP) | VAF 93/755 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TENM4 | c.3167G>A p.G1056D | Missense Mutation (SNP) | VAF 69/254 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- TNC | c.371G>T p.S124I | Missense Mutation (SNP) | VAF 105/355 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- TNFRSF19 | c.1237T>G p.S413A | Missense Mutation (SNP) | VAF 378/473 reads (80%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TP53 | c.636dup p.R213Sfs*3 | Frame Shift Ins (INS) | VAF 179/252 reads (71%) | called by mutect2, pindel, varscan2
- VPS13B | c.3309G>A p.W1103* | Nonsense Mutation (SNP) | VAF 26/369 reads (7%) | called by muse, mutect2
- VWA3A | c.923dup p.A309Cfs*11 | Frame Shift Ins (INS) | VAF 45/358 reads (13%) | called by mutect2, pindel, varscan2
- ADAMTSL5 | c.156G>T p.G52= | Silent (SNP) | VAF 203/326 reads (62%) | called by muse, mutect2, varscan2
- BCL11B | c.1572G>A p.P524= (on ENST00000357195 / NM_001282237.2; = p.P453= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 357/360 reads (99%) | catalogued as rs758740380; called by muse, varscan2
- BHMT2 | c.864C>T p.G288= | Silent (SNP) | VAF 180/405 reads (44%) | catalogued as rs755500242, COSV54872597; called by muse, mutect2, varscan2
- CNTN4 | c.1050A>G p.L350= | Silent (SNP) | VAF 13/234 reads (6%) | called by muse, mutect2
- COL13A1 | c.1506C>T p.R502= (on ENST00000398978 / NM_001130103.2; = p.R445= on NM_080798.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 109/255 reads (43%) | catalogued as rs754892079, COSV62568712; ClinVar: likely benign; called by muse, mutect2, varscan2
- DNAH3 | c.11727G>A p.S3909= | Silent (SNP) | VAF 97/580 reads (17%) | catalogued as rs758112425, COSV99767410; called by muse, mutect2, varscan2
- ERICH1 | c.804C>T p.D268= | Silent (SNP) | VAF 337/339 reads (99%) | catalogued as rs1387504904, COSV50640520; called by muse, mutect2, varscan2
- FAM241B | c.42C>T p.D14= | Silent (SNP) | VAF 208/466 reads (45%) | catalogued as rs769897866, COSV64767984; called by muse, mutect2, varscan2
- FAM47B | c.915C>T p.S305= | Silent (SNP) | VAF 156/346 reads (45%) | catalogued as rs377737946, COSV61454438; called by muse, mutect2, varscan2
- FAM47C | c.2664G>A p.K888= | Silent (SNP) | VAF 246/495 reads (50%) | catalogued as COSV63725664; called by muse, mutect2, varscan2
- FLT4 | c.1491C>T p.A497= | Silent (SNP) | VAF 201/422 reads (48%) | catalogued as rs751517485, COSV56106016; called by muse, mutect2, varscan2
- GPR179 | c.3477C>T p.N1159= (on ENST00000621958; = p.N1158= on NM_001004334.4) | Silent (SNP) | VAF 112/626 reads (18%) | catalogued as rs755044433; called by muse, mutect2, varscan2
- GPR32 | c.1008G>A p.A336= | Silent (SNP) | VAF 183/266 reads (69%) | catalogued as rs761150764, COSV54515212; called by muse, mutect2, varscan2
- GPR50 | c.1125A>G p.A375= | Silent (SNP) | VAF 147/667 reads (22%) | catalogued as rs1248593147; called by muse, mutect2, varscan2
- GRIN2D | c.3186G>A p.P1062= | Silent (SNP) | VAF 120/147 reads (82%) | catalogued as rs1274457454; called by muse, varscan2
- GRM4 | c.438G>A p.K146= | Silent (SNP) | VAF 179/441 reads (41%) | called by muse, mutect2, varscan2
- GSK3A | c.648C>T p.I216= | Silent (SNP) | VAF 28/322 reads (9%) | catalogued as rs768388588; called by muse, mutect2
- GSR | c.1116A>G p.A372= | Silent (SNP) | VAF 85/174 reads (49%) | called by muse, mutect2, varscan2
- ITGB3 | c.498C>T p.T166= | Silent (SNP) | VAF 49/398 reads (12%) | catalogued as COSV101457537; called by muse, mutect2, varscan2
- KCNA5 | c.273G>A p.P91= | Silent (SNP) | VAF 350/779 reads (45%) | called by muse, mutect2, varscan2
- MKRN3 | c.900G>A p.S300= | Silent (SNP) | VAF 302/302 reads (100%) | catalogued as COSV58810005; called by muse, mutect2, varscan2
- NALCN | c.5124C>T p.D1708= | Silent (SNP) | VAF 148/1005 reads (15%) | catalogued as rs1468254746, COSV51975679; called by muse, mutect2, varscan2
- NALCN | c.1248C>T p.D416= | Silent (SNP) | VAF 440/517 reads (85%) | catalogued as rs767226604, COSV51928622; called by muse, mutect2, varscan2
- NRXN1 | c.3846C>T p.A1282= | Silent (SNP) | VAF 210/449 reads (47%) | catalogued as rs1309946041, COSV60503131; ClinVar: likely benign; called by muse, mutect2, varscan2
- PDE3A | c.2601T>C p.N867= | Silent (SNP) | VAF 151/371 reads (41%) | called by muse, mutect2, varscan2
- PNMA2 | c.1089C>T p.D363= | Silent (SNP) | VAF 60/107 reads (56%) | catalogued as rs202002019; called by muse, mutect2, varscan2
- REXO1 | c.1143C>T p.T381= | Silent (SNP) | VAF 193/528 reads (37%) | catalogued as rs531507550; called by muse, mutect2, varscan2
- SCIN | c.825A>G p.A275= (on ENST00000297029 / NM_001112706.3; = p.A28= on NM_033128.3) | Silent (SNP) | VAF 170/567 reads (30%) | called by muse, mutect2, varscan2
- SEMG1 | c.237C>T p.S79= | Silent (SNP) | VAF 44/342 reads (13%) | catalogued as rs1461279518, COSV54874891, COSV99725573; called by muse, mutect2, varscan2
- SLC16A6 | c.633G>A p.P211= | Silent (SNP) | VAF 126/217 reads (58%) | catalogued as rs782764638; called by muse, mutect2
- SMC4 | c.1161A>G p.K387= | Silent (SNP) | VAF 101/149 reads (68%) | called by muse, mutect2, varscan2
- TECTA | c.3999C>T p.I1333= | Silent (SNP) | VAF 179/404 reads (44%) | catalogued as rs775746884, COSV99878734; called by muse, varscan2
- TMEM221 | c.669T>C p.C223= | Silent (SNP) | VAF 203/333 reads (61%) | called by muse, mutect2, varscan2
- TMPRSS15 | c.2751G>A p.T917= | Silent (SNP) | VAF 51/123 reads (41%) | catalogued as rs771004816; called by muse, mutect2, varscan2
- TRAPPC11 | c.2034G>A p.V678= | Silent (SNP) | VAF 73/75 reads (97%) | catalogued as rs965136707; called by muse, mutect2, varscan2
- TTN | c.12951G>A p.E4317= (on ENST00000591111; = p.E4271= on NM_003319.4) | Silent (SNP) | VAF 81/343 reads (24%) | called by muse, mutect2, varscan2
- UBE2J2 | c.222A>G p.K74= | Silent (SNP) | VAF 90/404 reads (22%) | called by muse, mutect2, varscan2
- ZC3H15 | c.321C>T p.F107= | Silent (SNP) | VAF 129/267 reads (48%) | catalogued as rs1241385474; called by muse, mutect2, varscan2
- ZDBF2 | c.2133G>A p.P711= | Silent (SNP) | VAF 174/365 reads (48%) | catalogued as rs373918151; called by muse, mutect2, varscan2
- ZNF217 | c.2052A>G p.E684= | Silent (SNP) | VAF 367/516 reads (71%) | catalogued as rs767921932, COSV56594143; called by muse, mutect2, varscan2
- ZNF526 | c.135C>T p.A45= | Silent (SNP) | VAF 69/365 reads (19%) | catalogued as rs756343377; called by muse, mutect2, varscan2
- ZNF568 | c.387G>A p.A129= | Silent (SNP) | VAF 79/263 reads (30%) | catalogued as rs1354238378, COSV70893646; called by muse, varscan2
- ZNF750 | c.309G>A p.Q103= | Silent (SNP) | VAF 149/398 reads (37%) | called by muse, mutect2, varscan2
- C6orf136 | c.72+146A>G | Intron (SNP) | VAF 408/888 reads (46%) | catalogued as rs977537787; called by muse, mutect2, varscan2
- DCHS2 | n.5277G>A | RNA (SNP) | VAF 188/190 reads (99%) | catalogued as rs1318829771, COSV100601211; called by muse, mutect2, varscan2
- IQCF6 | c.-16A>T | 5'UTR (SNP) | VAF 165/458 reads (36%) | called by muse, mutect2, varscan2
- IRAK1 | c.136+36C>T | Intron (SNP) | VAF 120/627 reads (19%) | called by muse, mutect2, varscan2
- LEKR1 | c.*900T>C | 3'UTR (SNP) | VAF 54/192 reads (28%) | called by muse, mutect2, varscan2
- MAST1 | c.1366+59G>A | Intron (SNP) | VAF 201/323 reads (62%) | catalogued as rs779163962; called by muse, mutect2, varscan2
